Gene-level copy-number profile of tumor specimen TCGA-VR-A8EU-01A from TCGA case TCGA-VR-A8EU, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 51.2 years (18,711 days).
Specimen TCGA-VR-A8EU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.92d8f4d8-31c9-4af5-bc6a-36b1b125da19.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8EU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dbc64149-f52f-4f2c-8dd6-b711210942e4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,178; copy number 2: 11,213; copy number 3: 30,038; copy number 4: 11,507; copy number 5: 3,605; copy number 6: 1,096; copy number 7: 284; copy number 8: 552; copy number 9: 40; copy number 10: 56; copy number 11: 110; copy number 16: 89; copy number 17: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8EU-01A-11D-A36I-01): tumor purity 0.57, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,586,626–140,683,888, 2 genes: MIR7157, COPRSP1.
- chr2:140,992,543–140,992,659, 1 gene: Y_RNA.
- chr3:54,874,605–54,967,088, 2 genes: CACNA2D3-AS1, LRTM1.
- chr8:3,700,492–4,329,027, 2 genes: RNA5SP251, AC027251.1.
- chr9:33,817,160–33,920,399, 1 gene (within-gene range 0–2): UBE2R2.
- chr9:33,868,540–33,868,665, 1 gene: RNU4ATAC11P.
- chr9:33,934,296–33,934,376, 1 gene: SNORD121B.
- chr11:80,751,200–81,431,520, 4 genes (within-gene range 0–1): LINC02720, AP003398.1, AP003398.2, AP003464.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,152 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:202,032,770–205,620,162, 69 genes, copy number 8–16 (within-gene range 1–16) (broad region; genes not listed).
- chr3:186,105,668–198,222,513, 279 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:22,854,126–25,751,032, 56 genes, copy number 7–10 (within-gene range 5–10): SNHG26, AC005682.1, RPL12P10, FAM126A, KLHL7-DT, KLHL7, AK3P3, NUP42, AC005082.2, AC005082.1, GPNMB, MALSU1, IGF2BP3, AC021876.1, SNORD65C, RNU7-143P, AC079780.1, RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14, AC005084.1, GSDME, AC003093.1, OSBPL3, SNRPCP19, CYCS, C7orf31, AC004129.2, AC004129.1, NPVF, AC004129.3, U3, TSEN15P3, AC003985.1, AC005100.1, AC005100.2, AC091705.1, AC005165.1.
- chr7:87,503,017–97,437,896, 148 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr7:97,963,658–114,693,772, 364 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr8:127,072,694–127,227,541, 1 gene, copy number 8 (within-gene range 4–8): CASC19.
- chr8:127,253,213–127,257,630, 1 gene, copy number 8: AC018714.2.
- chr8:127,292,233–127,420,066, 2 genes, copy number 8 (within-gene range 4–8): AC018714.1, POU5F1B.
- chr11:69,048,932–74,171,210, 174 genes, copy number 11–17 (within-gene range 3–17) (broad region; genes not listed).
- chr19:28,065,267–28,429,490, 5 genes, copy number 7: AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1.
- chr19:28,437,060–28,535,277, 1 gene, copy number 7 (within-gene range 3–7): AC005381.1.
- chr19:28,509,238–28,518,728, 1 gene, copy number 7: AC005616.1.
- chr20:24,445,391–26,188,191, 51 genes, copy number 7 (within-gene range 3–7): GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, AL035252.5, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P, FAM182B, BSNDP1, AL390198.2, BSNDP2, CFTRP1, LINC01733, FAM182A, AL078587.1, AL078587.2, AL450124.1, BSNDP3, NCOR1P1, AL391119.1, AL121904.2.

Autosomal genes at a single copy (total copy number 1): 470. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
